Somatic mutation profile of tumor specimen TCGA-2G-AAG5-01A (aliquot TCGA-2G-AAG5-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAG5, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Teratoma, benign; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 37.0 years (13,497 days).
Specimen TCGA-2G-AAG5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff5bffc1-8f81-4931-96c8-89f45dca9c97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAG5-10A (Blood Derived Normal), aliquot TCGA-2G-AAG5-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33f10330-5cf8-41d2-846d-28dd45b24078

The open-access MAF lists 20 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Intron 3, Frame Shift Del 1, RNA 1, Frame Shift Ins 1, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKHD1-EIF4EBP3 | c.826C>G p.L276V | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1399458872; called by muse, mutect2, varscan2
- PAF1 | c.364C>T p.Q122* | Nonsense Mutation (SNP) | VAF 29/77 reads (38%) | catalogued as rs757357536; called by muse, mutect2, varscan2
- ROBO3 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs759734850; called by muse, mutect2, varscan2
- USP13 | c.1896del p.I633* | Frame Shift Del (DEL) | VAF 29/112 reads (26%) | catalogued as rs780272979; called by mutect2, pindel, varscan2
- ANKRD60 | c.352G>C p.V118L | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.021); called by muse, mutect2
- ANTXR2 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 76/213 reads (36%) | SIFT tolerated (0.94); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AZU1 | c.741_746dup p.G249_P250dup | In Frame Ins (INS) | VAF 43/106 reads (41%) | called by mutect2, varscan2
- C16orf78 | c.489G>C p.E163D | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DBX1 | c.389A>G p.Q130R | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- DBX1 | c.388C>A p.Q130K | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- GPR37 | c.1754A>G p.N585S | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- SRCAP | c.4622dup p.A1542Gfs*306 | Frame Shift Ins (INS) | VAF 38/140 reads (27%) | called by mutect2, pindel, varscan2
- AGR3 | c.34T>C p.L12= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as COSV60037156; called by muse, mutect2, varscan2
- FUCA1 | c.15G>C p.G5= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs746017062; called by muse, mutect2, varscan2
- TNXB | c.6087G>A p.L2029= (on ENST00000647633; = p.L1782= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs376818111; called by muse, mutect2, varscan2
- ZNF697 | c.1536C>A p.R512= | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- ARPC1A | c.984-10T>A | Intron (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
- BBS2 | c.1226-31_1226-29del | Intron (DEL) | VAF 8/43 reads (19%) | called by pindel, varscan2
- FAM169B | n.747A>T | RNA (SNP) | VAF 42/136 reads (31%) | called by muse, mutect2, varscan2
- SPDL1 | c.1670+57G>A | Intron (SNP) | VAF 17/42 reads (40%) | catalogued as rs1168945558; called by muse, mutect2, varscan2
